Somatic mutation profile of tumor specimen ALCH-B027-TTP1-A (aliquot ALCH-B027-TTP1-A-1-0-D-A679-36) from ALCHEMIST case ALCH-B027, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.3 years (18,370 days).
Specimen ALCH-B027-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa758747-1ed1-41fb-954e-1de9eefa1c8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B027-NB1-A (Blood Derived Normal), aliquot ALCH-B027-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dfff6cc-17b9-4b6a-86be-94eaf81bd18c

The open-access MAF lists 62 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Nonsense Mutation 6, RNA 3, Intron 3, Splice Region 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA1 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 35/318 reads (11%) | catalogued as rs369717052, CM1511726, COSV62057121; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2235_2243del p.L747_E749del | In Frame Del (DEL) | VAF 127/724 reads (18%) | hotspot (GDC flag); catalogued as rs727504266; ClinVar: drug response; called by pindel, varscan2
- PTEN | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 232/682 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs121909223, CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 202/595 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs768495202; called by muse, varscan2
- ADCY2 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 31/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1379866152, COSV57871123; called by muse, mutect2
- CFAP46 | c.6791G>C p.R2264T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.331); catalogued as COSV99585176; called by muse, mutect2, varscan2
- CHMP7 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1477163149, COSV57533892; called by muse, mutect2, varscan2
- CNTNAP3 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1374325132, COSV52676102, COSV99905386; called by muse, mutect2, varscan2
- COL5A2 | c.1754G>C p.G585A | Missense Mutation (SNP) | VAF 402/912 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66409008, COSV66415961; called by muse, mutect2, varscan2
- DOCK3 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1341159051; called by muse, mutect2
- ERMN | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs1397868205; called by muse, mutect2
- FBXO4 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 84/452 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV55852431; called by muse, mutect2, varscan2
- HDAC9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1400537160, COSV67769993; called by muse, mutect2, varscan2
- PRRT3 | c.605C>G p.S202* | Nonsense Mutation (SNP) | VAF 30/314 reads (10%) | catalogued as rs887347679; called by muse, mutect2
- PRSS36 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 53/317 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as rs778099836; called by muse, mutect2, varscan2
- PXDNL | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs1432085650, COSV62478278, COSV62500583; called by muse, mutect2, varscan2
- SMC4 | c.2086T>G p.L696V | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV61006367; called by muse, mutect2
- TENM2 | c.4196G>A p.R1399Q (on ENST00000518659 / NM_001122679.2; = p.R1160Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 73/459 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs1489815338; called by muse, mutect2, varscan2
- TP63 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 236/683 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM056707; called by muse, mutect2, varscan2
- USP34 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as rs970997261, COSV68401706; called by muse, mutect2, varscan2
- XPR1 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 12/402 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1470862144; called by muse, mutect2
- ZBTB22 | c.1346C>G p.A449G | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1348598888; called by muse, mutect2, varscan2
- ACAP2 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 55/410 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL2 | c.3958C>A p.H1320N (on ENST00000370717 / NM_001366005.1; = p.H1264N on NM_012302.4) | Missense Mutation (SNP) | VAF 42/373 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CACNA1E | c.6280T>C p.S2094P (on ENST00000367573 / NM_001205293.3; = p.S2051P on NM_000721.4) | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CATSPERB | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 29/404 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2
- CRTC3 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP3A43 | c.412A>T p.T138S | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.272); called by muse, mutect2
- DNAH9 | c.8610A>T p.K2870N | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- EZR | c.1418C>A p.P473Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HARS1 | c.727A>T p.K243* | Nonsense Mutation (SNP) | VAF 69/292 reads (24%) | called by muse, mutect2, varscan2
- KCNAB2 | c.165A>G p.G55= | Splice Region (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- KIAA2012 | c.3286C>T p.R1096W | Missense Mutation (SNP) | VAF 59/568 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LCE1D | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 143/523 reads (27%) | PolyPhen possibly damaging (0.563); called by muse, varscan2
- MACC1 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MTMR8 | c.362A>T p.E121V | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- NISCH | c.670A>T p.I224L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPP1R3A | c.2530T>A p.S844T | Missense Mutation (SNP) | VAF 34/525 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.091); called by muse, mutect2
- RTN1 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 22/563 reads (4%) | called by muse, mutect2
- SCN10A | c.4211T>G p.F1404C | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.909_912del p.S303Rfs*41 | Frame Shift Del (DEL) | VAF 137/542 reads (25%) | called by mutect2, pindel, varscan2
- TSSK3 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.115); called by muse, mutect2
- USP6 | c.2619C>G p.Y873* | Nonsense Mutation (SNP) | VAF 42/298 reads (14%) | called by muse, mutect2, varscan2
- ABTB1 | c.1311C>T p.I437= (on ENST00000232744 / NM_172027.3; = p.I295= on NM_032548.3) | Silent (SNP) | VAF 64/214 reads (30%) | catalogued as rs1368464989; called by muse, mutect2, varscan2
- ANKRD17 | c.2346A>G p.Q782= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs754861434; called by muse, mutect2, varscan2
- AVPR1B | c.171G>A p.L57= | Silent (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- BAG5 | c.1305C>G p.L435= | Silent (SNP) | VAF 44/262 reads (17%) | called by muse, mutect2, varscan2
- C1QTNF7 | c.717G>A p.L239= | Silent (SNP) | VAF 14/428 reads (3%) | called by muse, mutect2
- CRACD | c.2466C>T p.S822= | Silent (SNP) | VAF 53/280 reads (19%) | catalogued as rs200636394, COSV51718667; called by muse, mutect2, varscan2
- DACT1 | c.1557C>A p.P519= | Silent (SNP) | VAF 34/356 reads (10%) | catalogued as COSV60019236; called by muse, mutect2
- EEPD1 | c.1146G>A p.A382= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs747171982; called by muse, mutect2, varscan2
- KCNS3 | c.603C>T p.A201= | Silent (SNP) | VAF 31/374 reads (8%) | catalogued as rs1467277569; called by muse, mutect2
- REL | c.1428C>A p.S476= | Silent (SNP) | VAF 30/293 reads (10%) | catalogued as COSV54363643; called by muse, mutect2, varscan2
- RP1L1 | c.6021G>T p.G2007= | Silent (SNP) | VAF 48/406 reads (12%) | called by muse, mutect2, varscan2
- UBN2 | c.1533T>A p.A511= | Silent (SNP) | VAF 20/555 reads (4%) | catalogued as COSV56028900; called by muse, mutect2
- VOPP1 | c.252C>T p.R84= | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as rs1284736028; called by muse, mutect2, varscan2
- LINC00587 | n.392A>G | RNA (SNP) | VAF 26/192 reads (14%) | called by muse, varscan2
- LINC00917 | n.1564+1528G>C | Intron (SNP) | VAF 19/266 reads (7%) | catalogued as rs1353730141; called by muse, mutect2
- LINC02610 | n.3013A>G | RNA (SNP) | VAF 28/224 reads (13%) | called by muse, mutect2, varscan2
- STK4 | c.1306-21908G>A | Intron (SNP) | VAF 40/270 reads (15%) | called by muse, varscan2
- ZNF849P | n.1094T>C | RNA (SNP) | VAF 84/306 reads (27%) | called by muse, varscan2
- ZRSR2 | c.203+1339del | Intron (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
